Somatic mutation profile of tumor specimen TCGA-CS-6188-01A (aliquot TCGA-CS-6188-01A-11D-1893-08) from TCGA case TCGA-CS-6188, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 48.5 years (17,729 days).
Specimen TCGA-CS-6188-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7003f87-f743-4f15-93b2-cbd4c26d6bfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-6188-10A (Blood Derived Normal), aliquot TCGA-CS-6188-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81078dbd-1b62-4d9d-b20d-be73a3998f8c

The open-access MAF lists 46 somatic variants for this specimen: 29 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 15, Splice Site 1, In Frame Del 1, Splice Region 1, Frame Shift Del 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1397_1399del p.L466del (on ENST00000521381 / NM_181523.3; = p.L196del on NM_181504.4) | In Frame Del (DEL) | VAF 15/59 reads (25%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AFG1L | c.877A>G p.K293E | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV64558789; called by muse, mutect2, varscan2
- ATP10B | c.2245C>T p.R749C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs752017849, COSV59166438; called by muse, mutect2, varscan2
- CDK11B | c.84G>C p.E28D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52364269; called by muse, mutect2, varscan2
- CDYL2 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs536459738, COSV73655115; called by muse, mutect2, varscan2
- CEP89 | c.1685A>G p.Q562R | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs748444728, COSV59868376; called by muse, mutect2, varscan2
- CLUH | c.1594C>T p.R532W (on ENST00000435359; = p.R570W on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs867623639, COSV70928916; called by muse, mutect2
- CRISP3 | c.432C>G p.I144M (on ENST00000371159 / NM_001368123.1; = p.I126M on NM_006061.4) | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs756277555, COSV53823817; called by muse, mutect2, varscan2
- DSP | c.1704G>A p.L568= | Splice Region (SNP) | VAF 125/356 reads (35%) | catalogued as COSV65796750; called by muse, mutect2, varscan2
- DSP | c.1775G>A p.R592K | Missense Mutation (SNP) | VAF 101/285 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.928); catalogued as COSV65796754; called by muse, mutect2, varscan2
- FDCSP | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV58764684, COSV58765451; called by muse, mutect2, varscan2
- GPC5 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV65599440, COSV65633589; called by muse, mutect2, varscan2
- HGS | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61267782; called by muse, mutect2, varscan2
- HJURP | c.1050G>C p.K350N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV64979694; called by muse, mutect2, varscan2
- KIF20B | c.3667C>T p.L1223F (on ENST00000371728 / NM_001284259.2; = p.L1183F on NM_016195.4) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV53316745; called by muse, mutect2, varscan2
- LILRA2 | c.1099C>G p.L367V | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV52198374; called by muse, mutect2, varscan2
- LRRC17 | c.5G>A p.R2H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1235030077, COSV50867341, COSV50867734; called by muse, mutect2, varscan2
- MYOCD | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs531377746, COSV58500836; called by muse, mutect2, varscan2
- NCAPG | c.2903C>T p.T968I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52273172; called by muse, mutect2, varscan2
- NOTCH2 | c.1916-2A>G p.X639_splice | Splice Site (SNP) | VAF 14/56 reads (25%) | catalogued as COSV56708720; called by muse, mutect2, varscan2
- NUP210L | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs745416091, COSV55141814; called by muse, mutect2, varscan2
- OLFM1 | c.703G>A p.D235N (on ENST00000371793 / NM_001282611.2; = p.D217N on NM_014279.5) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.329); catalogued as COSV53283115; called by muse, mutect2, varscan2
- PCDHA4 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as rs1554125084, COSV63541767; called by muse, mutect2, varscan2
- RIPK4 | c.2482C>T p.R828W (on ENST00000352483; = p.R780W on NM_020639.3) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as rs140909597; called by muse, mutect2, varscan2
- SHROOM1 | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV60582793; called by muse, mutect2, varscan2
- SLC2A3 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50008704; called by muse, mutect2, varscan2
- SLC36A2 | c.867G>T p.M289I | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV58865508; called by muse, mutect2, varscan2
- TRA2B | c.545T>G p.M182R | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV52026544; called by muse, mutect2, varscan2
- FAM135B | c.3450del p.N1151Tfs*8 | Frame Shift Del (DEL) | VAF 28/126 reads (22%) | called by mutect2, pindel, varscan2
- ACIN1 | c.666G>A p.R222= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as COSV52983033; called by muse, mutect2, varscan2
- ADAMTS12 | c.1467C>T p.C489= | Silent (SNP) | VAF 29/149 reads (19%) | catalogued as COSV61283057; called by muse, mutect2, varscan2
- ADGRB3 | c.3282C>T p.N1094= | Silent (SNP) | VAF 52/206 reads (25%) | catalogued as rs138734026; called by muse, mutect2, varscan2
- C7 | c.1074C>T p.N358= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs147954006, COSV57477368; called by muse, mutect2
- CABP2 | c.585C>T p.D195= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs753451816, COSV53709378; called by muse, mutect2, varscan2
- COL1A2 | c.1689C>T p.P563= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs183493537, COSV51954726; called by muse, mutect2, varscan2
- FAT2 | c.8271C>T p.H2757= | Silent (SNP) | VAF 50/170 reads (29%) | catalogued as rs749656015, COSV55831405; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPATCH1 | c.2319A>G p.Q773= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV50130758; called by muse, mutect2, varscan2
- HLA-F | c.852C>T p.H284= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs374197706; called by muse, mutect2, varscan2
- OR2L8 | c.93T>C p.V31= | Silent (SNP) | VAF 78/241 reads (32%) | catalogued as COSV61728728; called by muse, mutect2, varscan2
- OR2T8 | c.100T>C p.L34= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV60665303; called by muse, mutect2, varscan2
- PLA2G4D | c.1281G>C p.L427= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV51824454; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2901G>A p.S967= | Silent (SNP) | VAF 44/137 reads (32%) | catalogued as rs1163400210, COSV54762261, COSV54764671; called by muse, mutect2, varscan2
- RELN | c.966G>A p.E322= | Silent (SNP) | VAF 69/254 reads (27%) | catalogued as rs1214570292, COSV59038501; called by muse, mutect2, varscan2
- ZNF555 | c.840C>T p.G280= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs148620935; called by muse, mutect2, varscan2
- OR3A4P | n.714G>A | RNA (SNP) | VAF 43/125 reads (34%) | called by muse, mutect2, varscan2
- VPS11 | c.-1050C>T | 5'UTR (SNP) | VAF 14/38 reads (37%) | catalogued as rs1219631965, COSV56186735; called by muse, mutect2, varscan2
